Somatic mutation profile of tumor specimen MP2PRT-PAVYJG-TMP1-A (aliquot MP2PRT-PAVYJG-TMP1-A-1-0-D-A81A-36) from MP2PRT case MP2PRT-PAVYJG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.5 years (1,654 days).
Specimen MP2PRT-PAVYJG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 05353c1f-06e8-46e7-9c43-0094fcca3e4e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVYJG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVYJG-NB1-A-1-0-D-A81A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9557bba6-e0b1-4eb7-b7ce-3c1f390daa7c

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Silent 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2508_2510del p.I836del | In Frame Del (DEL) | VAF 64/188 reads (34%) | catalogued as rs121913490; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- KRBOX4 | c.473A>T p.K158I (on ENST00000344302 / NM_001129898.2; = p.K153I on NM_017776.2) | Missense Mutation (SNP) | VAF 74/276 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as COSV53343807; called by muse, mutect2, varscan2
- NAV3 | c.6170C>T p.P2057L (on ENST00000397909 / NM_001024383.2; = p.P2035L on NM_014903.6) | Missense Mutation (SNP) | VAF 106/293 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- P2RX6 | c.834C>A p.D278E | Missense Mutation (SNP) | VAF 16/322 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.103); called by muse, mutect2
- PRDM16 | c.2686C>T p.P896S | Missense Mutation (SNP) | VAF 82/257 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- UBB | c.482C>T p.T161I | Missense Mutation (SNP) | VAF 101/480 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- XBP1 | c.587_588delinsCCCTATCGA p.L196Pfs*193 | Frame Shift Ins (INS) | VAF 64/186 reads (34%) | called by pindel, varscan2*
- XPO4 | c.1490C>T p.T497I | Missense Mutation (SNP) | VAF 15/256 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.079); called by muse, mutect2
- PLEKHM3 | c.2169G>A p.P723= | Silent (SNP) | VAF 129/335 reads (39%) | catalogued as rs763750479, COSV70136498; called by muse, mutect2, varscan2
